Gene-level copy-number profile of tumor specimen BLGSP-71-08-00022-01A from CGCI case BLGSP-71-08-00022, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.7 years (2,458 days).
Specimen BLGSP-71-08-00022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed8d8b37-5888-402c-a1ed-4bae78faf02a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-08-00022-12A (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,762 have no estimate.
https://portal.gdc.cancer.gov/files/de8748f5-67df-456c-af5c-f4f13bffdc1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,062; copy number 2: 54,397; copy number 3: 1,402.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 254. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
